Somatic mutation profile of tumor specimen ALCH-B05W-TTP1-A (aliquot ALCH-B05W-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B05W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,187 days).
Specimen ALCH-B05W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e64293bb-fb14-4304-906a-74d5380215fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B05W-NB1-A (Blood Derived Normal), aliquot ALCH-B05W-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c91eb8c-904a-44d7-8aa0-36abb697be19

The open-access MAF lists 886 somatic variants for this specimen: 601 protein-altering or splice-affecting, 164 silent, 121 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 517, Silent 164, Intron 55, Nonsense Mutation 43, RNA 21, 5'UTR 16, Frame Shift Del 15, 3'UTR 14, Splice Region 12, 5'Flank 10, Splice Site 9, 3'Flank 5.

Variants (750 of 886; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 113/534 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 26/271 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519872, COSV55911123; ClinVar: not provided; called by muse, mutect2
- ABCA13 | c.7531G>T p.D2511Y | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV71290226; called by muse, mutect2, varscan2
- ABCA6 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs1303898462, COSV99446281; called by muse, mutect2, varscan2
- ABCG8 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 56/474 reads (12%) | catalogued as COSV55391996; called by muse, mutect2, varscan2
- ACTL9 | c.1237C>A p.R413S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs781918753; called by muse, mutect2, varscan2
- ACTRT2 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1163318195, COSV101007503; called by muse, mutect2
- ADARB1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771170713; called by muse, mutect2, varscan2
- ADGRB3 | c.3901G>A p.E1301K | Missense Mutation (SNP) | VAF 38/477 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs867238592, COSV53255642; called by muse, mutect2
- ADGRG4 | c.3809G>A p.R1270K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs760443810; called by muse, mutect2
- AIM2 | c.521A>T p.Q174L | Missense Mutation (SNP) | VAF 68/707 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV63698082; called by muse, mutect2
- ANKRD33B | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs968447109, COSV56976851; called by muse, mutect2
- ARHGAP36 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52264613; called by muse, mutect2
- ARHGAP36 | c.799C>A p.R267S | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1256533982, COSV52267805, COSV99357197; called by muse, mutect2
- ARID5A | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 27/475 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1445565872; called by muse, mutect2
- ARIH1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as COSV65910337; called by muse, mutect2
- ARVCF | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); catalogued as rs774446606; called by muse, mutect2, varscan2
- ASXL2 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55455696, COSV55469069; called by muse, mutect2
- ATP1A4 | c.1730T>A p.F577Y | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100927636; called by muse, mutect2
- ATP4A | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52868011; called by muse, mutect2
- BICD2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs201293367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C6 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 68/732 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54710078; called by muse, mutect2
- C7orf31 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV52217278; called by muse, mutect2, varscan2
- CACNA1E | c.4409G>C p.R1470P | Missense Mutation (SNP) | VAF 33/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62387568; called by muse, mutect2
- CCDC39 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 45/450 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1182604379, COSV56482150, COSV56483486; called by muse, mutect2, varscan2
- CCDC63 | c.177G>A p.Q59= | Splice Region (SNP) | VAF 56/531 reads (11%) | catalogued as COSV100370134; called by muse, mutect2, varscan2
- CCT8L2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as rs1263893382, COSV63463986; called by muse, mutect2, varscan2
- CD101 | c.1473G>A p.W491* | Nonsense Mutation (SNP) | VAF 54/505 reads (11%) | catalogued as COSV99869248; called by muse, mutect2, varscan2
- CDH9 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50384520, COSV99144061; called by muse, mutect2
- CDH9 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 82/491 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50262194; called by muse, mutect2, varscan2
- CDKN1B | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 85/467 reads (18%) | catalogued as COSV57431591, COSV99963866; called by muse, mutect2, varscan2
- CHIC1 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as rs1286940342; called by muse, mutect2, varscan2
- CLASP1 | c.4335G>C p.M1445I | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as COSV55329935; called by muse, mutect2
- CLCA1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs146483639; called by mutect2, varscan2
- CNTNAP4 | c.2200C>T p.Q734* | Nonsense Mutation (SNP) | VAF 42/388 reads (11%) | catalogued as COSV56689668; called by muse, mutect2, varscan2
- COL22A1 | c.4042G>T p.G1348* | Nonsense Mutation (SNP) | VAF 71/396 reads (18%) | catalogued as COSV57363282; called by muse, mutect2, varscan2
- COL4A1 | c.2317G>T p.G773* | Nonsense Mutation (SNP) | VAF 69/605 reads (11%) | catalogued as CM123624, CM1410951, COSV101011529; called by muse, mutect2, varscan2
- COQ7 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 54/491 reads (11%) | catalogued as COSV58982538; called by muse, mutect2
- CRMP1 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100271540; called by muse, mutect2, varscan2
- CTAGE9 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 202/1115 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs755181349, COSV100020638; called by muse, mutect2, varscan2
- CTNNA2 | c.2334C>A p.Y778* | Nonsense Mutation (SNP) | VAF 21/225 reads (9%) | catalogued as COSV58168777; called by muse, mutect2, varscan2
- CTTNBP2 | c.3928T>A p.W1310R | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50455311; called by muse, mutect2, varscan2
- CYP24A1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 115/736 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs779409222; called by muse, mutect2, varscan2
- DCAF8L1 | c.1657C>A p.R553S | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV71595229; called by muse, mutect2
- DCK | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99709067; called by muse, mutect2, varscan2
- DCTN1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.996); catalogued as COSV100720977; called by muse, mutect2
- DDX3X | c.1598G>A p.R533H (on ENST00000399959; = p.R534H on NM_001356.5) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as CM158021, COSV67863295; called by muse, varscan2
- DEFB110 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.873); catalogued as COSV64484682; called by muse, mutect2
- DEFB118 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53620878; called by muse, mutect2
- DNAH11 | c.1817G>T p.C606F | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100180593; called by muse, mutect2, varscan2
- DNAH9 | c.4805C>A p.P1602Q | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361896; called by muse, mutect2
- DPP6 | c.2581G>T p.D861Y (on ENST00000377770 / NM_001364500.2; = p.D799Y on NM_001936.5) | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59651383; called by muse, mutect2
- DPPA4 | c.907T>C p.W303R | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs193920923, COSV59512051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPY19L2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 29/467 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.09); catalogued as COSV60542119; called by muse, mutect2
- DYSF | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1368149283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM133A | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV104398314; called by muse, mutect2, varscan2
- FAM135B | c.756C>A p.Y252* | Nonsense Mutation (SNP) | VAF 16/332 reads (5%) | catalogued as COSV52746667; called by muse, mutect2
- FAXDC2 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV58171441, COSV58172617; called by muse, mutect2, varscan2
- FBL | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99695200; called by muse, mutect2, varscan2
- FCGBP | c.11791C>T p.R3931C | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs1190090196; called by muse, mutect2
- FCHO1 | c.1712G>T p.C571F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV53184409; called by muse, mutect2
- FERD3L | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV51763074; called by muse, mutect2, varscan2
- FGD1 | c.1565G>T p.R522L | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002775, COSV64308119; called by muse, mutect2, varscan2
- FGD5 | c.4376C>T p.A1459V | Missense Mutation (SNP) | VAF 67/644 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771379491, COSV99549520; called by muse, mutect2, varscan2
- FRMD6 | c.1546G>A p.V516I (on ENST00000344768 / NM_001267046.2; = p.V508I on NM_152330.4) | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1389501602; called by muse, mutect2
- FSIP2 | c.7612G>T p.V2538L | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1559028871; called by muse, mutect2
- GFM1 | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 46/469 reads (10%) | catalogued as rs747437028; called by muse, mutect2
- GLI2 | c.3863C>A p.P1288H (on ENST00000361492 / NM_001374353.1; = p.P1305H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.259); catalogued as COSV58033891; called by muse, mutect2
- GRIK4 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs369721630; called by muse, mutect2, varscan2
- GTF3C1 | c.4780G>T p.D1594Y | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649691; called by muse, mutect2
- GYG2 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | catalogued as rs376200058; called by muse, mutect2, varscan2
- HEPACAM2 | c.831del p.N278Tfs*22 (on ENST00000394468 / NM_001039372.4; = p.N266Tfs*22 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/395 reads (11%) | catalogued as rs1299788313; called by mutect2, pindel, varscan2
- HPCA | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 34/245 reads (14%) | catalogued as COSV65103299; called by muse, mutect2, varscan2
- HYDIN | c.6979C>A p.R2327S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs753881195; called by mutect2, varscan2
- IGKV3D-20 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 95/396 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs747231469; called by muse, mutect2, varscan2
- IL20RA | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360189; called by muse, mutect2
- INSYN2B | c.1348C>A p.R450S | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912355; called by muse, mutect2, varscan2
- IPCEF1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV54543617; called by muse, varscan2
- IQCC | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 68/548 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.135); catalogued as rs1292518069; called by muse, mutect2, varscan2
- IRAK4 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 79/458 reads (17%) | catalogued as rs1321134418; called by muse, mutect2, varscan2
- ITGA9 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 44/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53240435; called by muse, mutect2
- ITGB1BP1 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs775757013, COSV53006112; called by muse, mutect2, varscan2
- JAK2 | c.1763G>C p.R588T | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101072738; called by muse, mutect2, varscan2
- KCNB2 | c.1180G>C p.G394R | Missense Mutation (SNP) | VAF 109/649 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049981; called by muse, mutect2, varscan2
- KLK15 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV56826514; called by muse, mutect2, varscan2
- KPRP | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100908703, COSV64221042; called by muse, mutect2, varscan2
- KRT27 | c.971C>A p.T324K | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV56973375; called by muse, mutect2, varscan2
- KRTAP13-3 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs754309333, COSV61879058; called by muse, mutect2, varscan2
- LAMA1 | c.891C>A p.C297* | Nonsense Mutation (SNP) | VAF 97/805 reads (12%) | catalogued as rs749281239, COSV67535137; called by muse, mutect2, varscan2
- LAMA4 | c.1540C>T p.R514W (on ENST00000230538 / NM_001105206.3; = p.R507W on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs782767592, COSV57896200; called by muse, mutect2
- LIPI | c.356G>T p.R119M | Missense Mutation (SNP) | VAF 77/685 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV60709476; called by muse, mutect2, varscan2
- LRFN5 | c.1022C>A p.T341K | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769136851; called by muse, mutect2
- LRFN5 | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 83/647 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs758729700, COSV53250037; called by muse, mutect2, varscan2
- LRRC71 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1367574519; called by muse, mutect2
- MAG | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764252583, COSV62701894; called by muse, mutect2, varscan2
- MAGEC1 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs950366317; called by muse, mutect2, varscan2
- MAGEC3 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV100025240; called by muse, mutect2, varscan2
- MARCHF7 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778493903; called by muse, mutect2
- MARVELD2 | c.1303A>C p.K435Q | Missense Mutation (SNP) | VAF 26/612 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV57781749; called by muse, mutect2
- MRPL39 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 72/485 reads (15%) | catalogued as COSV100220877; called by muse, mutect2, varscan2
- MTNR1A | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 153/751 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1448073163; called by muse, mutect2, varscan2
- MUC16 | c.12881C>T p.S4294F | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.223); catalogued as COSV67455835; called by muse, mutect2
- MUC16 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as rs371358566; called by muse, mutect2, varscan2
- MYH11 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1243698832; called by muse, mutect2, varscan2
- MYOZ2 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 72/666 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV61085991; called by muse, mutect2, varscan2
- NALCN | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 36/644 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51958807; called by muse, mutect2
- NAV1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs753588783; called by muse, mutect2, varscan2
- NIBAN2 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs145531660; called by muse, mutect2, varscan2
- NOP53 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.17); catalogued as rs867575407; called by muse, mutect2, varscan2
- NTRK3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV58144872; called by muse, mutect2
- NWD2 | c.4931C>A p.T1644K | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV58752394; called by muse, mutect2, varscan2
- OR11L1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV63315706; called by muse, mutect2
- OR13J1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs779397899; called by muse, mutect2, varscan2
- OR4N2 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 47/973 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60054082; called by muse, mutect2
- OR7C2 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99934472; called by muse, mutect2, varscan2
- P2RX5 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs754806273; called by muse, mutect2, varscan2
- PAK5 | c.1852C>A p.L618I | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV62020388; called by muse, mutect2
- PCDH10 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 44/590 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414341703, COSV52104612; called by muse, mutect2
- PCDHA4 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 100/918 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs201303975; called by muse, varscan2
- PCDHB15 | c.986del p.G329Efs*19 | Frame Shift Del (DEL) | VAF 66/599 reads (11%) | catalogued as COSV51076506; called by mutect2, pindel, varscan2
- PDGFC | c.588G>T p.L196F | Missense Mutation (SNP) | VAF 77/918 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99925919; called by muse, mutect2
- PMS1 | c.2344C>G p.L782V | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV59715514; called by muse, mutect2, varscan2
- POTEC | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 58/1006 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.205); catalogued as COSV100743333; called by muse, mutect2
- POU6F1 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 74/649 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100374867; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV53450885; called by muse, mutect2, varscan2
- PSD3 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as rs746212174, COSV58977851; called by muse, mutect2, varscan2
- PSPC1 | c.1444A>G p.R482G | Missense Mutation (SNP) | VAF 35/628 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.879); catalogued as rs1401411917; called by muse, mutect2
- PTPN7 | c.412C>A p.L138I (on ENST00000495688; = p.L177I on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036370353, COSV58312119; called by muse, mutect2
- PTPRB | c.3722G>T p.W1241L | Missense Mutation (SNP) | VAF 78/446 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54233314, COSV99718273; called by muse, mutect2, varscan2
- PTPRH | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558110066, COSV54745822; called by muse, mutect2, varscan2
- PTPRN2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs747387074, COSV67028535; called by muse, mutect2, varscan2
- RBM26 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV57390903, COSV99936720; called by muse, mutect2
- RFX4 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 68/628 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100774951; called by muse, varscan2
- RNF213 | c.5266C>T p.R1756C | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs769571061; called by muse, mutect2
- ROBO3 | c.1984T>C p.W662R | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs762961186; called by muse, mutect2, varscan2
- RPS3A | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV56839263; called by muse, mutect2
- RUNX1T1 | c.1466C>A p.T489K (on ENST00000265814 / NM_001198628.1; = p.T462K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs781778214, COSV56146311; called by muse, mutect2, varscan2
- RYR2 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV63670725; called by muse, varscan2
- RYR2 | c.7901C>A p.S2634* | Nonsense Mutation (SNP) | VAF 26/702 reads (4%) | catalogued as COSV100772171; called by muse, mutect2
- SBK1 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777428755; called by muse, mutect2, varscan2
- SCN11A | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as COSV56565565; called by muse, mutect2
- SERPINI2 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV52987417; called by muse, mutect2
- SHROOM3 | c.3580G>T p.G1194C | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99935809; called by muse, mutect2
- SLC35G5 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1187737594; called by muse, mutect2, varscan2
- SPATS1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.708); catalogued as COSV55821855; called by muse, mutect2, varscan2
- SPECC1L | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 89/733 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58656972; called by muse, mutect2, varscan2
- SPHKAP | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs915922377, COSV100764087; called by muse, mutect2
- SRCAP | c.7096del p.A2366Lfs*109 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as COSV99351426; called by mutect2, pindel, varscan2
- STK11 | c.309G>C p.R103S | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as CD147064; called by muse, mutect2, varscan2
- TCERG1L | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104424533; called by muse, mutect2, varscan2
- TCTE1 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV65255043; called by muse, mutect2, varscan2
- TENM2 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1483086467; called by muse, mutect2
- TEX35 | c.543C>A p.C181* | Nonsense Mutation (SNP) | VAF 41/554 reads (7%) | catalogued as COSV51104632; called by muse, mutect2
- THBS3 | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 62/638 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV57426178; called by muse, mutect2
- TIAM1 | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 58/478 reads (12%) | catalogued as COSV54554597; called by muse, mutect2, varscan2
- TNN | c.1834G>C p.A612P | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV53436206; called by muse, mutect2, varscan2
- TRABD2A | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59103405; called by muse, mutect2
- TRIM42 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 33/215 reads (15%) | catalogued as COSV53883965; called by muse, mutect2, varscan2
- TRIM8 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV56661328; called by muse, mutect2
- TRPA1 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 77/763 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100082781; called by muse, mutect2, varscan2
- TSPAN17 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs754616228; called by muse, mutect2, varscan2
- TTN | c.99922C>G p.R33308G (on ENST00000591111; = p.R25884G on NM_003319.4) | Missense Mutation (SNP) | VAF 40/456 reads (9%) | PolyPhen probably damaging (0.998); catalogued as COSV59888459; called by muse, mutect2
- TTN | c.46963C>T p.R15655C (on ENST00000591111; = p.R8231C on NM_003319.4) | Missense Mutation (SNP) | VAF 44/551 reads (8%) | PolyPhen probably damaging (0.998); catalogued as rs1028433729, COSV60065542, COSV60364572; called by muse, mutect2
- UNC13C | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.106); catalogued as rs866582846; called by muse, mutect2, varscan2
- UNC5D | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99773465; called by muse, mutect2, varscan2
- WDR17 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV54572712; called by muse, mutect2
- WDR17 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54579789; called by muse, mutect2, varscan2
- Z83844.2 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60928594; called by muse, mutect2, varscan2
- ZC3H11A | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV100142066; called by muse, mutect2
- ZC3H13 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.478); catalogued as COSV99668743; called by muse, mutect2
- ZFHX4 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 78/489 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51479262; called by muse, mutect2, varscan2
- ZKSCAN8 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332150130; called by muse, mutect2
- ZNF292 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104411601, COSV60537540; called by muse, mutect2, varscan2
- ZNF454 | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); catalogued as COSV60766624; called by muse, mutect2, varscan2
- ZNF625 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV63242671; called by muse, mutect2
- ZNF628 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99220415; called by muse, mutect2
- ZNF850 | c.2693A>G p.D898G | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs1475096453; called by muse, mutect2
- ZP4 | c.313A>T p.M105L | Missense Mutation (SNP) | VAF 30/554 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV63911830; called by muse, mutect2
- ZXDB | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 44/511 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.041); catalogued as rs1226389845; called by muse, mutect2, varscan2
- AARS2 | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 66/734 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ABTB1 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AC011005.1 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 36/934 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.288); called by muse, mutect2
- ACKR1 | c.725G>T p.W242L | Missense Mutation (SNP) | VAF 166/485 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM9 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ADAMTS12 | c.1251C>A p.Y417* | Nonsense Mutation (SNP) | VAF 72/316 reads (23%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS20 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAMTS7 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 29/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADD1 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 49/682 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.309); called by muse, mutect2
- ADGRA3 | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 82/610 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, varscan2
- ADGRF1 | c.7G>T p.V3F | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- ADGRL4 | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- AGGF1 | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 94/1044 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- AHCTF1 | c.5151A>T p.K1717N (on ENST00000366508; = p.K1691N on NM_015446.5) | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHNAK2 | c.10044G>T p.Q3348H | Missense Mutation (SNP) | VAF 58/531 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AKR1B1 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 82/742 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- AKR1B15 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKR1B15 | c.964A>T p.R322* | Nonsense Mutation (SNP) | VAF 120/627 reads (19%) | called by muse, mutect2, varscan2
- ANK2 | c.3375T>A p.D1125E | Missense Mutation (SNP) | VAF 108/893 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3851A>G p.N1284S | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANKIB1 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ANKRD30B | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- APBB1IP | c.1556C>G p.P519R | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ARFGAP1 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ARFGEF2 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 86/1010 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2
- ARIH1 | c.652A>T p.T218S | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.093); called by muse, mutect2
- ARMC3 | c.199G>T p.G67* | Nonsense Mutation (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- ASB14 | c.878del p.G293Afs*4 | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | called by mutect2, pindel, varscan2
- ASB15 | c.23A>T p.D8V | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASCC2 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ASCL4 | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ASTN1 | c.2722C>A p.L908M | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); called by muse, varscan2
- ATAD2B | c.2640G>A p.E880= | Splice Region (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
- ATXN3L | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2
- BCLAF1 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- BSG | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- BTNL2 | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C10orf82 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1orf94 | c.180C>G p.D60E | Missense Mutation (SNP) | VAF 69/613 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C21orf91 | c.520A>T p.M174L | Missense Mutation (SNP) | VAF 53/526 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- C7 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CA4 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2
- CA4 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2
- CACNA1B | c.6685A>T p.S2229C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CACNA1H | c.4038G>T p.K1346N | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CALD1 | c.1837G>A p.A613T (on ENST00000361675 / NM_033138.4; = p.A358T on NM_004342.7) | Missense Mutation (SNP) | VAF 29/363 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CARD6 | c.547G>T p.V183F | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CATSPER1 | c.372G>C p.R124S | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2
- CCDC168 | c.14464G>T p.V4822L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC62 | c.1607G>T p.S536I | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2
- CCDC7 | c.1314A>T p.K438N | Missense Mutation (SNP) | VAF 96/452 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CCNYL2 | n.700T>A | Splice Region (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- CCT5 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 107/1349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD55 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 45/674 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD58 | c.743+5G>T | Splice Region (SNP) | VAF 44/401 reads (11%) | called by muse, mutect2, varscan2
- CDH12 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- CDH7 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH8 | c.1361T>G p.L454R | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK6 | c.851A>T p.N284I | Missense Mutation (SNP) | VAF 73/387 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CEP57L1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 46/553 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CERT1 | c.2036T>G p.V679G (on ENST00000405807 / NM_001130105.1; = p.V551G on NM_005713.3) | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- CFAP46 | c.8051C>T p.S2684F | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2
- CHD2 | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 74/629 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHPF | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHRNA3 | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CHRNA7 | c.298G>C p.V100L | Missense Mutation (SNP) | VAF 29/418 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CLCN2 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 94/550 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CNTNAP5 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, varscan2
- COL11A1 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 72/710 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.1321G>T p.G441C | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL5A1 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 63/531 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- COPB2 | c.1942G>T p.A648S | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CPS1 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 56/792 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPS1 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 55/694 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRISP3 | c.613G>T p.A205S (on ENST00000371159 / NM_001368123.1; = p.A187S on NM_006061.4) | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CROCC | c.2389C>A p.Q797K | Missense Mutation (SNP) | VAF 29/498 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2
- CROCC2 | c.2531T>A p.L844Q | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CUL9 | c.5888A>T p.Q1963L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCHS2 | c.1283A>T p.E428V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX51 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB110 | c.22T>A p.F8I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2
- DEFB119 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- DENND4B | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 168/524 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- DEPDC1 | c.1255A>G p.R419G | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DNAH5 | c.7837A>G p.M2613V | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.9672G>T p.R3224S | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAH8 | c.6587G>T p.G2196V | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNER | c.1241T>A p.F414Y | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.995); called by muse, mutect2
- DOCK10 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 102/418 reads (24%) | called by muse, mutect2, varscan2
- DOCK7 | c.5504G>T p.W1835L (on ENST00000635253 / NM_001367561.1; = p.W1804L on NM_033407.3) | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2
- DSE | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 49/465 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- EBF1 | c.1613C>G p.S538W | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- EDAR | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- EMX2 | c.690T>A p.H230Q | Missense Mutation (SNP) | VAF 102/785 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EOMES | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EPB41L4B | c.1733T>C p.L578P | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EPO | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ETFRF1 | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EXOC5 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- F13A1 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 41/750 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM170B | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM184B | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); called by muse, mutect2
- FAM187B | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); called by muse, mutect2
- FAM98A | c.992A>T p.Q331L | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2
- FANCB | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- FANCF | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 137/525 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- FBN2 | c.4717+1G>C p.X1573_splice | Splice Site (SNP) | VAF 48/782 reads (6%) | called by muse, mutect2
- FBN2 | c.4717G>T p.D1573Y | Missense Mutation (SNP) | VAF 50/796 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO24 | c.845C>T p.P282L (on ENST00000241071 / NM_033506.3; = p.P320L on NM_012172.5) | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FCGBP | c.3164T>A p.V1055E | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FER1L5 | c.937T>G p.F313V (on ENST00000623019; = p.F330V on NM_001293083.2) | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); called by muse, mutect2
- FGD5 | c.3495C>G p.S1165R | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FGFR2 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 57/503 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- FLG | c.12013C>G p.P4005A | Missense Mutation (SNP) | VAF 198/1411 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- FLG | c.4754dup p.T1586Dfs*10 | Frame Shift Ins (INS) | VAF 96/606 reads (16%) | called by mutect2, pindel, varscan2
- FLG2 | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); called by muse, mutect2
- FLG2 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2
- FOXC1 | c.967A>G p.S323G | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FOXN1 | c.1837C>G p.L613V | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.033); called by muse, mutect2
- FRMPD2 | c.2656C>A p.L886M | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); called by mutect2, varscan2
- FRYL | c.5303A>T p.H1768L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- FSIP2 | c.19513C>A p.Q6505K | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FTO | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- GABRA4 | c.1475C>A p.T492N | Missense Mutation (SNP) | VAF 92/656 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRQ | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2
- GALNT13 | c.1395+8C>T | Splice Region (SNP) | VAF 26/712 reads (4%) | called by muse, mutect2
- GALNT9 | c.84C>A p.C28* | Nonsense Mutation (SNP) | VAF 43/268 reads (16%) | called by muse, mutect2, varscan2
- GAPT | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 25/424 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2
- GEN1 | c.2558G>A p.C853Y | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA12 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 32/614 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.152); called by muse, mutect2
- GNRHR | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 16/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPRC6A | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 48/419 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- GPX5 | c.160G>T p.V54F | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); called by muse, mutect2
- GRID2 | c.2477T>C p.L826P | Missense Mutation (SNP) | VAF 46/1028 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIK1 | c.2163G>A p.W721* | Nonsense Mutation (SNP) | VAF 51/264 reads (19%) | called by muse, mutect2, varscan2
- GRIN2A | c.1960A>T p.I654F | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIN3A | c.2864T>A p.V955E | Missense Mutation (SNP) | VAF 101/923 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRIN3A | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 78/647 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- GRIN3A | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); called by muse, varscan2
- GRM4 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- HCN1 | c.1967C>A p.P656Q | Missense Mutation (SNP) | VAF 164/1808 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- HEATR5B | c.5997del p.D2001Ifs*10 | Frame Shift Del (DEL) | VAF 33/326 reads (10%) | called by mutect2, pindel, varscan2
- HINFP | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 33/608 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HPX | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 86/361 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- HSD3B7 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 62/526 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- HSD3B7 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 60/524 reads (11%) | called by muse, mutect2, varscan2
- HSF1 | c.565-4A>G | Splice Region (SNP) | VAF 42/412 reads (10%) | called by muse, mutect2, varscan2
- HSPG2 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 42/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HYDIN | c.1723G>T p.G575C | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-33 | c.349A>T p.R117* | Nonsense Mutation (SNP) | VAF 30/446 reads (7%) | called by muse, mutect2
- IGSF1 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 38/554 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGSF21 | c.1065del p.D357Tfs*3 | Frame Shift Del (DEL) | VAF 44/401 reads (11%) | called by mutect2, varscan2
- IKBKG | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INHA | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); called by muse, mutect2
- IQCB1 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 91/770 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ITGB4 | c.4378A>T p.R1460W | Missense Mutation (SNP) | VAF 74/456 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- JARID2 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNH5 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- KCNK17 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCTD3 | c.1589G>T p.C530F | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2
- KIF19 | c.2670G>T p.K890N | Missense Mutation (SNP) | VAF 38/649 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF21B | c.1465C>A p.R489= | Splice Region (SNP) | VAF 23/425 reads (5%) | called by muse, mutect2
- KLC4 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- KLHDC3 | c.536G>T p.W179L | Missense Mutation (SNP) | VAF 110/383 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KLK2 | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- KRT5 | c.1256A>C p.Q419P | Missense Mutation (SNP) | VAF 91/554 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRT9 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 56/497 reads (11%) | PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- KRTAP25-1 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- LAIR1 | c.71-5C>A | Splice Region (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- LAMB4 | c.2771C>A p.A924D | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- LIPN | c.1116C>A p.N372K | Missense Mutation (SNP) | VAF 66/657 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LPAR3 | c.824A>T p.K275I | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC15 | c.1053C>A p.N351K | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC7 | c.4330C>T p.Q1444* (on ENST00000651989 / NM_001370785.2; = p.Q1364* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 46/752 reads (6%) | called by muse, mutect2
- LRRC71 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2
- LRRC8D | c.971G>C p.C324S | Missense Mutation (SNP) | VAF 62/531 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC9 | c.1805A>G p.Q602R | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.358); called by muse, mutect2
- LRRK1 | c.5733G>T p.K1911N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- LRRN1 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 27/580 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LSR | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); called by muse, mutect2
- LTBP1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- MAEL | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 25/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- MAGEA1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEA12 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MAP2 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); called by muse, mutect2
- MAST1 | c.2780C>A p.P927Q | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- MCAM | c.295del p.A99Lfs*5 | Frame Shift Del (DEL) | VAF 41/209 reads (20%) | called by mutect2, pindel, varscan2
- MCOLN1 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 54/434 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- MEGF8 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- METTL21C | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- MFAP2 | c.343A>T p.K115* | Nonsense Mutation (SNP) | VAF 58/584 reads (10%) | called by muse, mutect2
- MGAM2 | c.5666C>A p.T1889N | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- MIER3 | c.1480A>C p.N494H (on ENST00000381199 / NM_001297599.2; = p.N493H on NM_152622.4) | Missense Mutation (SNP) | VAF 74/1004 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.332); called by muse, mutect2
- MIOS | c.1938G>T p.L646F | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MMP16 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MRC1 | c.3692C>A p.P1231Q | Missense Mutation (SNP) | VAF 32/973 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MRPS30 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2
- MUC22 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT deleterious (0.01); called by muse, mutect2
- MYO16 | c.4336G>C p.G1446R | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- MYO18B | c.7006G>T p.G2336C | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MYO1B | c.3055G>T p.D1019Y (on ENST00000304164; = p.D961Y on NM_012223.5) | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYOC | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 58/1268 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2
- MYOM3 | c.3179del p.K1060Rfs*6 | Frame Shift Del (DEL) | VAF 33/316 reads (10%) | called by mutect2, varscan2
- MYRFL | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by mutect2, varscan2
- MYRFL | c.1830+1G>T p.X610_splice | Splice Site (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- NALCN | c.637A>G p.K213E | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAT8L | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- NBAS | c.3315G>T p.M1105I | Missense Mutation (SNP) | VAF 62/599 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NCAPH2 | c.1379C>A p.A460E | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NEBL | c.2677C>T p.L893F | Missense Mutation (SNP) | VAF 197/938 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- NEK3 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 39/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEK6 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NELL1 | c.2038C>A p.L680I | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2
- NKX6-3 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NOS3 | c.2323A>G p.T775A | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NOVA2 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NR0B1 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- NRAP | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 64/656 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NRXN3 | c.2980A>T p.M994L (on ENST00000335750 / NM_001330195.2; = p.M621L on NM_004796.6) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- NT5C1A | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NXF3 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- OBSCN | c.12682G>C p.G4228R | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.12683G>T p.G4228V | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPLAH | c.2512G>T p.V838L | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OPTC | c.946T>A p.F316I | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2
- OR10Z1 | c.791C>A p.A264D | Missense Mutation (SNP) | VAF 70/848 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- OR14A16 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR1C1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 20/493 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR1I1 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2A25 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 102/979 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR2M7 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 52/734 reads (7%) | called by muse, mutect2
- OR2T12 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- OR2T4 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 125/1291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4C46 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2
- OR5M1 | c.534C>A p.Y178* | Nonsense Mutation (SNP) | VAF 93/307 reads (30%) | called by muse, mutect2, varscan2
- OR6Q1 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 59/543 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OSBPL3 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 59/516 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- OTOF | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- OTUD4 | c.2468T>G p.L823R (on ENST00000447906 / NM_001366057.1; = p.L758R on NM_001102653.1) | Missense Mutation (SNP) | VAF 73/395 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PACS1 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1720G>T p.V574L (on ENST00000259318 / NM_001136562.3; = p.V805L on NM_007203.5) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- PAPPA2 | c.2242G>T p.V748F | Missense Mutation (SNP) | VAF 35/506 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAPPA2 | c.3856G>T p.G1286C | Missense Mutation (SNP) | VAF 40/696 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAQR6 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PATE3 | c.48G>T p.V16= | Splice Region (SNP) | VAF 64/299 reads (21%) | called by muse, mutect2, varscan2
- PCDH11X | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 80/835 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PCDHB5 | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA11 | c.2189A>G p.E730G | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PCLO | c.11524A>T p.T3842S | Missense Mutation (SNP) | VAF 51/477 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCNX1 | c.3494A>T p.Y1165F | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.97); called by muse, varscan2
- PDE3B | c.2000A>G p.Y667C | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PIGO | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 45/444 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKP2 | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 26/643 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.056); called by muse, mutect2
- PLB1 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 33/448 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLEKHG3 | c.1822C>T p.Q608* (on ENST00000394691; = p.Q664* on NM_001308147.2) | Nonsense Mutation (SNP) | VAF 29/254 reads (11%) | called by muse, mutect2, varscan2
- PLIN3 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- PMM2 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 48/750 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); called by muse, mutect2
- POLR3G | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2
- POM121L2 | c.1951G>T p.A651S | Missense Mutation (SNP) | VAF 56/527 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- POMT2 | c.1892-7G>T | Splice Region (SNP) | VAF 60/455 reads (13%) | called by muse, mutect2, varscan2
- POTED | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 153/796 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPIP5K1 | c.3578G>T p.G1193V (on ENST00000396923; = p.G1168V on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); called by muse, mutect2
- PPP1R3A | c.1540_1541insT p.G514Vfs*2 | Frame Shift Ins (INS) | VAF 32/314 reads (10%) | called by mutect2, pindel*
- PRDM11 | c.1480del p.V494Ffs*3 (on ENST00000530656 / NM_001359633.1; = p.V460Ffs*3 on NM_001256696.1) | Frame Shift Del (DEL) | VAF 92/396 reads (23%) | called by mutect2, pindel*, varscan2
- PREPL | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- PREX2 | c.160A>T p.N54Y | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PRF1 | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 78/658 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PRICKLE1 | c.2359del p.R787Gfs*60 | Frame Shift Del (DEL) | VAF 51/550 reads (9%) | called by pindel, varscan2*
- PRKAG3 | c.377del p.A126Efs*24 | Frame Shift Del (DEL) | VAF 21/180 reads (12%) | called by mutect2, pindel, varscan2
- PRKD1 | c.1468C>G p.H490D | Missense Mutation (SNP) | VAF 32/359 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- PRKN | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 94/908 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRNP | c.255T>G p.H85Q | Missense Mutation (SNP) | VAF 54/523 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRR16 | c.572del p.P191Lfs*36 (on ENST00000407149 / NM_001300783.2; = p.P168Lfs*36 on NM_016644.2) | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by mutect2, pindel
- PRRT1 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- PSG7 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTN | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 51/224 reads (23%) | called by muse, mutect2, varscan2
- PTPRD | c.5534+1G>T p.X1845_splice | Splice Site (SNP) | VAF 53/482 reads (11%) | called by muse, mutect2, varscan2
- PTPRH | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); called by muse, mutect2
- PTPRZ1 | c.5308G>T p.A1770S | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.151); called by muse, mutect2
- PXDNL | c.900A>T p.Q300H | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- RAD51AP2 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RBL1 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- RCBTB1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- RHEB | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RIMBP2 | c.2770C>T p.Q924* | Nonsense Mutation (SNP) | VAF 43/348 reads (12%) | called by muse, mutect2, varscan2
- RNASE13 | c.379A>T p.S127C | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ROBO4 | c.1172C>A p.S391* | Nonsense Mutation (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- RPRD2 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 85/1150 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- RPTN | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 66/1106 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2
- RTN1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- RTP5 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.088); called by mutect2, varscan2
- RTTN | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- RYR1 | c.2771C>A p.S924Y | Missense Mutation (SNP) | VAF 101/537 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.12263G>T p.C4088F (on ENST00000389232; = p.C4089F on NM_001036.6) | Missense Mutation (SNP) | VAF 79/564 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SACS | c.9643G>C p.A3215P | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.454); called by muse, mutect2
- SACS | c.2857A>G p.T953A | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD9 | c.667_669del p.A223del | In Frame Del (DEL) | VAF 44/428 reads (10%) | called by mutect2, pindel
- SCARA3 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- SCN1A | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCUBE1 | c.1541C>A p.P514Q | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SDS | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SENP6 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- SEPTIN6 | c.529-1G>T p.X177_splice | Splice Site (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- SERPINA3 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 100/619 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SETBP1 | c.4752G>C p.Q1584H | Missense Mutation (SNP) | VAF 19/512 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- SETD2 | c.2231G>T p.S744I | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SEZ6L2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.367); called by mutect2, varscan2
- SH3TC2 | c.1134C>G p.L378= | Splice Region (SNP) | VAF 114/1289 reads (9%) | called by muse, mutect2
- SHE | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.412); called by muse, mutect2
- SIGLEC8 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SIRT2 | c.665A>G p.E222G | Missense Mutation (SNP) | VAF 80/425 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SKOR1 | c.2834G>A p.C945Y | Missense Mutation (SNP) | VAF 58/548 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC12A1 | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, varscan2
- SLC17A3 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 58/654 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.274); called by muse, mutect2
- SLC18A2 | c.499T>A p.C167S | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- SLC24A1 | c.1343A>G p.E448G | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- SLIT1 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK2 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.276); called by muse, mutect2
- SLITRK5 | c.2142C>A p.Y714* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- SND1 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRPA | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORCS1 | c.1977G>T p.Q659H | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPATA3 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SPATS1 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SPEF2 | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 42/657 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.326); called by muse, mutect2
- SPOCK3 | c.822A>T p.R274S | Missense Mutation (SNP) | VAF 50/694 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.183); called by muse, mutect2
- SPPL3 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 63/398 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTA1 | c.2824G>C p.E942Q | Missense Mutation (SNP) | VAF 82/914 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SPTA1 | c.2495T>A p.L832Q | Missense Mutation (SNP) | VAF 139/1286 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SPTBN1 | c.3366G>T p.R1122S | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2
- SPTBN2 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 44/728 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRPRB | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- SSH2 | c.4064A>C p.Q1355P | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ST7L | c.693A>T p.L231F | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- STAC | c.522del p.L175Cfs*75 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | called by mutect2, pindel, varscan2
- STAC | c.832-2A>T p.X278_splice | Splice Site (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2, varscan2
- STARD9 | c.6271G>T p.E2091* | Nonsense Mutation (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- STARD9 | c.7711A>T p.R2571W | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- STK35 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.055); called by muse, mutect2
- SUPT20HL1 | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 27/238 reads (11%) | called by muse, mutect2, varscan2
- SV2C | c.210C>A p.N70K | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SYDE1 | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS2R41 | c.687C>G p.H229Q | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TAS2R60 | c.178G>T p.V60F | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2
- TBC1D21 | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- TBCD | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TEX55 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 78/654 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TFAP2C | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 127/669 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TFAP2D | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 56/607 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TGM1 | c.183G>C p.W61C | Missense Mutation (SNP) | VAF 31/363 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.339); called by muse, mutect2
- THEG | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- THSD1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- THSD7B | c.1796G>C p.R599P | Missense Mutation (SNP) | VAF 143/525 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TLE2 | c.2123A>G p.Q708R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TMEM120A | c.273dup p.G92Rfs*5 | Frame Shift Ins (INS) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- TMEM147 | c.429+8G>T | Splice Region (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2
- TMTC1 | c.694T>A p.Y232N (on ENST00000539277 / NM_001193451.2; = p.Y124N on NM_175861.3) | Missense Mutation (SNP) | VAF 30/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMTC1 | c.692T>G p.V231G (on ENST00000539277 / NM_001193451.2; = p.V123G on NM_175861.3) | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- TNKS1BP1 | c.2290A>G p.R764G | Missense Mutation (SNP) | VAF 117/457 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC6B | c.5051del p.G1684Afs*4 (on ENST00000454349 / NM_001162501.2; = p.G1574Afs*4 on NM_015088.3) | Frame Shift Del (DEL) | VAF 41/362 reads (11%) | called by mutect2, pindel, varscan2
- TOPAZ1 | c.3989A>T p.N1330I | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TRAJ34 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 38/345 reads (11%) | called by muse, varscan2
- TRBV24-1 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM26 | c.1081A>T p.K361* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- TRIM36 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.67); called by muse, mutect2
- TRIM36 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 20/473 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2
- TRIP6 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- TRPC4 | c.687del p.E229Dfs*2 | Frame Shift Del (DEL) | VAF 95/675 reads (14%) | called by mutect2, pindel, varscan2
- TRPC5 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- TSHZ3 | c.2829G>T p.M943I | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- TSPAN9 | c.63+1G>A p.X21_splice | Splice Site (SNP) | VAF 78/458 reads (17%) | called by muse, mutect2, varscan2
- TTC34 | c.2911G>T p.G971C | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2
- TTN | c.102227A>C p.Q34076P (on ENST00000591111; = p.Q26652P on NM_003319.4) | Missense Mutation (SNP) | VAF 27/235 reads (11%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.58028G>A p.W19343* (on ENST00000591111; = p.W11919* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- TTN | c.52235T>C p.L17412S (on ENST00000591111; = p.L9988S on NM_003319.4) | Missense Mutation (SNP) | VAF 36/398 reads (9%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.40619C>A p.A13540D (on ENST00000591111; = p.A6116D on NM_003319.4) | Missense Mutation (SNP) | VAF 110/1179 reads (9%) | PolyPhen benign (0.107); called by muse, mutect2
- TTN | c.17356+1G>A p.X5786_splice (on ENST00000591111; = p.X4859_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- UGDH | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 37/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UNC5C | c.1562G>T p.S521I | Missense Mutation (SNP) | VAF 58/422 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- UNC80 | c.5302T>A p.C1768S | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, varscan2
- USH2A | c.4153C>A p.P1385T | Missense Mutation (SNP) | VAF 51/1017 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP11 | c.1175A>T p.Q392L (on ENST00000218348; = p.Q349L on NM_001371072.1) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- USP21 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 35/467 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP32 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- USP35 | c.2528A>G p.Q843R | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.82); called by muse, mutect2
- USP7 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 18/556 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VAT1L | c.345C>G p.D115E | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS13B | c.2251G>T p.G751* | Nonsense Mutation (SNP) | VAF 106/924 reads (11%) | called by muse, mutect2, varscan2
- VSTM2B | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.027); called by muse, mutect2
- VWDE | c.4660T>C p.C1554R | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- VWF | c.4272G>T p.Q1424H | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASHC2C | c.3904G>C p.G1302R (on ENST00000336378; = p.G1281R on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/581 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- WDR43 | c.1881G>T p.E627D | Missense Mutation (SNP) | VAF 39/327 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR45B | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- WRN | c.157A>T p.I53F | Missense Mutation (SNP) | VAF 59/477 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- YPEL3 | c.284A>G p.E95G (on ENST00000398838 / NM_001145524.2; = p.E133G on NM_031477.5) | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ZBED3 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZC3H11A | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- ZDBF2 | c.2674A>G p.K892E | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFHX4 | c.1984C>A p.H662N | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZGPAT | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF28 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZNF311 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 38/702 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ZNF397 | c.617T>G p.L206R | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2
- ZNF454 | c.934A>T p.R312W | Missense Mutation (SNP) | VAF 45/425 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZNF502 | c.1311C>A p.C437* | Nonsense Mutation (SNP) | VAF 42/350 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF564 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF573 | c.520G>T p.G174C (on ENST00000536220 / NM_001172692.1; = p.G116C on NM_152360.3) | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2
- ZNF573 | c.518G>T p.S173I (on ENST00000536220 / NM_001172692.1; = p.S115I on NM_152360.3) | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.205); called by muse, mutect2
- ZNF680 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 49/542 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ZNF716 | c.1196dup p.R400Efs*12 | Frame Shift Ins (INS) | VAF 68/402 reads (17%) | called by pindel, varscan2
- ZNF787 | c.397T>C p.W133R | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- ZNF790 | c.191G>T p.W64L | Missense Mutation (SNP) | VAF 34/477 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2
- ZNF804A | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF813 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF99 | c.2456G>T p.C819F | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZP4 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 13/202 reads (6%) | called by muse, mutect2
- ZRANB3 | c.161+1G>T p.X54_splice | Splice Site (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- ACACA | c.1848G>A p.K616= | Silent (SNP) | VAF 40/1174 reads (3%) | called by muse, mutect2
- ACSS3 | c.243C>A p.A81= | Silent (SNP) | VAF 176/972 reads (18%) | catalogued as COSV99698283; called by muse, mutect2, varscan2
- ACTN2 | c.468T>A p.G156= | Silent (SNP) | VAF 62/907 reads (7%) | called by muse, mutect2
- AFF2 | c.2652C>A p.I884= | Silent (SNP) | VAF 32/381 reads (8%) | called by muse, mutect2
- AHSG | c.783A>G p.P261= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- AKAP1 | c.1761C>G p.L587= | Silent (SNP) | VAF 46/450 reads (10%) | catalogued as rs752529110; called by muse, mutect2, varscan2
- ANK2 | c.6744T>G p.S2248= | Silent (SNP) | VAF 45/427 reads (11%) | catalogued as COSV52181375; called by muse, mutect2, varscan2
- APC | c.3792A>C p.V1264= | Silent (SNP) | VAF 34/273 reads (12%) | catalogued as COSV57351085; called by muse, mutect2, varscan2
- ARID1A | c.6711G>T p.A2237= | Silent (SNP) | VAF 12/127 reads (9%) | called by mutect2, varscan2
- ASTL | c.1167C>T p.A389= | Silent (SNP) | VAF 37/465 reads (8%) | catalogued as rs563654187, COSV60904645; called by muse, mutect2
- ATP2B2 | c.2184G>T p.R728= (on ENST00000352432; = p.R694= on NM_001683.5) | Silent (SNP) | VAF 35/310 reads (11%) | called by muse, mutect2, varscan2
- B4GALNT2 | c.621G>T p.L207= | Silent (SNP) | VAF 49/462 reads (11%) | catalogued as COSV55926011; called by muse, mutect2, varscan2
- B4GALT2 | c.279G>C p.T93= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- BHLHE40 | c.840A>G p.Q280= | Silent (SNP) | VAF 74/683 reads (11%) | catalogued as rs201910376; called by muse, mutect2, varscan2
- BICRA | c.642C>G p.L214= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1251012468; called by muse, mutect2, varscan2
- BTBD7 | c.3249C>T p.P1083= | Silent (SNP) | VAF 83/562 reads (15%) | catalogued as rs767237944; called by muse, mutect2, varscan2
- BTN2A1 | c.837G>C p.L279= | Silent (SNP) | VAF 173/660 reads (26%) | catalogued as rs376460941; called by muse, mutect2, varscan2
- C16orf96 | c.3396G>A p.R1132= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- C6 | c.2727G>A p.L909= | Silent (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- CABP2 | c.249G>A p.L83= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- CCDC136 | c.2934C>A p.A978= | Silent (SNP) | VAF 40/340 reads (12%) | called by muse, mutect2, varscan2
- CCDC27 | c.120C>T p.C40= | Silent (SNP) | VAF 26/492 reads (5%) | catalogued as rs1417267931; called by muse, mutect2
- CCN2 | c.633G>A p.K211= | Silent (SNP) | VAF 34/612 reads (6%) | called by muse, mutect2
- CD163 | c.2442G>A p.A814= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs759518221, COSV100776118; called by muse, mutect2
- CDH10 | c.2061G>A p.R687= | Silent (SNP) | VAF 222/1282 reads (17%) | catalogued as rs1027042839, COSV52571026, COSV52573259; called by muse, mutect2, varscan2
- CDH10 | c.1888C>T p.L630= | Silent (SNP) | VAF 28/232 reads (12%) | called by muse, varscan2
- CEP290 | c.4101G>A p.K1367= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- CFAP57 | c.2592G>A p.E864= | Silent (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- CHD7 | c.6222G>T p.L2074= | Silent (SNP) | VAF 114/697 reads (16%) | called by muse, mutect2, varscan2
- CLEC18A | c.1290C>T p.Y430= | Silent (SNP) | VAF 74/1262 reads (6%) | catalogued as rs576896247; called by muse, mutect2
- CMSS1 | c.459G>A p.K153= | Silent (SNP) | VAF 45/353 reads (13%) | called by muse, mutect2, varscan2
- CMYA5 | c.10956C>T p.A3652= | Silent (SNP) | VAF 40/369 reads (11%) | catalogued as rs769944134, COSV71405910; called by muse, mutect2
- CNKSR2 | c.6T>A p.A2= | Silent (SNP) | VAF 74/755 reads (10%) | called by muse, mutect2
- COL28A1 | c.2049A>T p.V683= | Silent (SNP) | VAF 22/221 reads (10%) | called by muse, mutect2
- COL6A3 | c.4728G>A p.R1576= | Silent (SNP) | VAF 22/370 reads (6%) | catalogued as COSV55091142; called by muse, mutect2
- CPPED1 | c.682C>A p.R228= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1284805365, COSV55499845; called by muse, mutect2
- CREBBP | c.3123G>A p.Q1041= | Silent (SNP) | VAF 43/664 reads (6%) | called by muse, mutect2
- CTNNA3 | c.231C>A p.A77= | Silent (SNP) | VAF 43/340 reads (13%) | called by muse, mutect2, varscan2
- DCN | c.606C>T p.L202= | Silent (SNP) | VAF 87/508 reads (17%) | catalogued as COSV50007638; called by muse, mutect2, varscan2
- DGKI | c.669G>A p.E223= | Silent (SNP) | VAF 59/517 reads (11%) | called by muse, mutect2, varscan2
- DNM2 | c.1416G>A p.K472= | Silent (SNP) | VAF 104/461 reads (23%) | catalogued as COSV58958527; called by muse, mutect2, varscan2
- DSC3 | c.15G>T p.G5= | Silent (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- DYNC1H1 | c.2145G>T p.G715= | Silent (SNP) | VAF 114/770 reads (15%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.3327G>T p.G1109= | Silent (SNP) | VAF 21/250 reads (8%) | called by muse, mutect2
- EPHA3 | c.1668C>A p.L556= | Silent (SNP) | VAF 53/507 reads (10%) | catalogued as COSV60698208, COSV60726682; called by muse, mutect2, varscan2
- FCGBP | c.2760G>T p.T920= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- FCRL5 | c.570A>T p.T190= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- FLG2 | c.6699C>A p.A2233= | Silent (SNP) | VAF 87/1067 reads (8%) | called by muse, mutect2
- FSIP2 | c.6129C>T p.N2043= | Silent (SNP) | VAF 32/361 reads (9%) | catalogued as rs1304442940; called by muse, mutect2
- FSIP2 | c.16065A>G p.V5355= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- GAD2 | c.1482G>A p.V494= | Silent (SNP) | VAF 32/292 reads (11%) | catalogued as rs1422139298; called by muse, mutect2, varscan2
- GDF11 | c.639C>A p.G213= | Silent (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- GPR50 | c.99C>T p.C33= | Silent (SNP) | VAF 38/374 reads (10%) | catalogued as rs756964167, COSV54439645; called by muse, mutect2
- GPRC6A | c.1371T>C p.D457= | Silent (SNP) | VAF 32/322 reads (10%) | catalogued as rs773862585; called by muse, mutect2
- GRIN2A | c.891C>T p.G297= | Silent (SNP) | VAF 44/448 reads (10%) | called by muse, mutect2
- GRIN3B | c.2541C>A p.L847= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- GRM8 | c.1716C>A p.I572= | Silent (SNP) | VAF 104/396 reads (26%) | catalogued as COSV100285097; called by muse, mutect2, varscan2
- H2AC6 | c.162G>T p.A54= | Silent (SNP) | VAF 22/255 reads (9%) | called by muse, mutect2
- HJV | c.6G>A p.G2= | Silent (SNP) | VAF 230/582 reads (40%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.1107T>C p.N369= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2
- HOXA7 | c.147G>T p.S49= | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as rs758081235, COSV99636154; called by muse, mutect2
- IL1A | c.534T>A p.A178= | Silent (SNP) | VAF 34/402 reads (8%) | catalogued as rs375126259; called by muse, mutect2
- INPP4A | c.759G>T p.V253= | Silent (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- INS | c.300C>T p.C100= | Silent (SNP) | VAF 80/314 reads (25%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.522C>A p.I174= | Silent (SNP) | VAF 77/723 reads (11%) | catalogued as rs149958309, COSV54598603; called by muse, mutect2
- KCNH1 | c.156G>C p.L52= | Silent (SNP) | VAF 153/482 reads (32%) | called by muse, mutect2, varscan2
- KCNS2 | c.471C>T p.D157= | Silent (SNP) | VAF 67/397 reads (17%) | catalogued as rs762692688, COSV54640205; called by muse, mutect2, varscan2
- KCNV2 | c.1149C>A p.R383= | Silent (SNP) | VAF 119/683 reads (17%) | called by muse, mutect2, varscan2
- KIF1B | c.921G>A p.R307= (on ENST00000377086 / NM_001365952.1; = p.R301= on NM_015074.3) | Silent (SNP) | VAF 40/444 reads (9%) | called by muse, mutect2
- KRT13 | c.351C>A p.S117= | Silent (SNP) | VAF 41/514 reads (8%) | called by muse, mutect2
- KRT27 | c.120C>A p.G40= | Silent (SNP) | VAF 17/325 reads (5%) | called by muse, mutect2
- L3MBTL3 | c.2241C>T p.D747= | Silent (SNP) | VAF 39/354 reads (11%) | called by muse, mutect2, varscan2
- LAMA4 | c.2424A>T p.A808= (on ENST00000230538 / NM_001105206.3; = p.A801= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/796 reads (5%) | called by muse, mutect2
- LILRB1 | c.1407C>T p.P469= (on ENST00000427581; = p.P433= on NM_006669.6) | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs1192002857; called by muse, mutect2, varscan2
- LILRB3 | c.375C>A p.T125= | Silent (SNP) | VAF 38/446 reads (9%) | catalogued as COSV99558614; called by muse, mutect2
- LRIT1 | c.1285C>A p.R429= | Silent (SNP) | VAF 29/276 reads (11%) | catalogued as COSV64513437; called by muse, mutect2, varscan2
- LRRC7 | c.4329C>A p.I1443= (on ENST00000651989 / NM_001370785.2; = p.I1363= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/745 reads (6%) | called by muse, mutect2
- LRRN3 | c.2124C>A p.S708= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs760953118, COSV57823823; called by mutect2, varscan2
- MCC | c.1204C>A p.R402= | Silent (SNP) | VAF 60/316 reads (19%) | catalogued as rs780382141, COSV100202398, COSV56734496; called by muse, mutect2, varscan2
- MTNR1A | c.228G>T p.V76= | Silent (SNP) | VAF 154/756 reads (20%) | called by muse, mutect2, varscan2
- MYCN | c.87C>T p.Y29= | Silent (SNP) | VAF 45/495 reads (9%) | called by muse, mutect2
- MYEOV | c.267G>T p.A89= | Silent (SNP) | VAF 50/534 reads (9%) | catalogued as COSV58293778; called by muse, mutect2
- MYH11 | c.2070G>T p.L690= | Silent (SNP) | VAF 39/362 reads (11%) | called by muse, mutect2, varscan2
- MZT2B | c.120G>A p.L40= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs1477324998; called by muse, mutect2
- NIN | c.5226G>C p.T1742= (on ENST00000382041 / NM_182946.1; = p.T1029= on NM_016350.4) | Silent (SNP) | VAF 34/349 reads (10%) | called by muse, mutect2, varscan2
- NLGN4X | c.252A>T p.G84= | Silent (SNP) | VAF 63/507 reads (12%) | called by muse, mutect2, varscan2
- NRXN1 | c.3699G>T p.V1233= | Silent (SNP) | VAF 49/505 reads (10%) | catalogued as COSV60487416; called by muse, mutect2, varscan2
- NVL | c.678A>G p.K226= | Silent (SNP) | VAF 60/450 reads (13%) | catalogued as rs376072933; called by muse, mutect2, varscan2
- OAS3 | c.3033C>T p.Y1011= | Silent (SNP) | VAF 34/289 reads (12%) | catalogued as rs923783442, COSV57446245; called by muse, mutect2, varscan2
- OR10W1 | c.177G>T p.G59= | Silent (SNP) | VAF 124/453 reads (27%) | called by muse, mutect2, varscan2
- OR14K1 | c.382C>T p.L128= | Silent (SNP) | VAF 82/442 reads (19%) | catalogued as COSV51722602; called by muse, mutect2, varscan2
- OR2L5 | c.399C>A p.I133= | Silent (SNP) | VAF 75/1074 reads (7%) | catalogued as COSV62365342; called by muse, mutect2
- OR2M3 | c.285T>C p.A95= | Silent (SNP) | VAF 40/947 reads (4%) | called by muse, mutect2
- OR2T2 | c.183C>T p.Y61= | Silent (SNP) | VAF 156/1951 reads (8%) | called by muse, mutect2
- OR2T33 | c.816G>T p.V272= | Silent (SNP) | VAF 46/1348 reads (3%) | called by muse, mutect2
- OR2W1 | c.168T>C p.H56= | Silent (SNP) | VAF 62/787 reads (8%) | catalogued as COSV101013918; called by muse, mutect2
- OR2W3 | c.495C>G p.R165= | Silent (SNP) | VAF 15/315 reads (5%) | catalogued as rs1474621011; called by muse, mutect2
- OR6B3 | c.21C>A p.T7= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100097359; called by muse, varscan2
- OR8H3 | c.177C>T p.P59= | Silent (SNP) | VAF 36/446 reads (8%) | catalogued as COSV57907491; called by muse, mutect2
- PCDHB9 | c.834C>A p.S278= | Silent (SNP) | VAF 52/261 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1731G>C p.L577= | Silent (SNP) | VAF 45/592 reads (8%) | called by muse, mutect2
- PCDHGB5 | c.1749G>A p.L583= | Silent (SNP) | VAF 40/351 reads (11%) | catalogued as rs1236470363; called by muse, mutect2, varscan2
- PDZD8 | c.438G>T p.R146= | Silent (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- PKHD1 | c.8436A>G p.K2812= | Silent (SNP) | VAF 62/1034 reads (6%) | called by muse, mutect2
- PLCL2 | c.2928G>T p.V976= (on ENST00000615277 / NM_001144382.2; = p.V850= on NM_015184.5) | Silent (SNP) | VAF 37/724 reads (5%) | called by muse, mutect2
- PNMA3 | c.615G>A p.L205= | Silent (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- POC1B-GALNT4 | c.63C>T p.I21= | Silent (SNP) | VAF 47/676 reads (7%) | catalogued as rs765729797; called by muse, mutect2
- PON2 | c.1020G>T p.L340= | Silent (SNP) | VAF 45/425 reads (11%) | called by muse, mutect2
- PPFIBP1 | c.1083C>A p.S361= (on ENST00000318304 / NM_177444.3; = p.S344= on NM_003622.4) | Silent (SNP) | VAF 23/211 reads (11%) | called by muse, mutect2, varscan2
- PRKCB | c.336C>A p.P112= | Silent (SNP) | VAF 28/314 reads (9%) | catalogued as COSV57805403; called by muse, mutect2
- PROX1 | c.1743A>T p.S581= | Silent (SNP) | VAF 35/465 reads (8%) | called by muse, mutect2
- PRPF4B | c.2646C>G p.L882= | Silent (SNP) | VAF 32/288 reads (11%) | called by muse, mutect2
- RAB6B | c.270G>C p.V90= | Silent (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2, varscan2
- RARB | c.216C>A p.V72= (on ENST00000383772 / NM_001290216.2; = p.V65= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/255 reads (18%) | called by muse, mutect2, varscan2
- REG3A | c.390C>T p.Y130= | Silent (SNP) | VAF 24/357 reads (7%) | catalogued as rs1440643069, COSV59412392; called by muse, mutect2
- RELN | c.9489T>C p.S3163= | Silent (SNP) | VAF 128/1103 reads (12%) | called by muse, mutect2, varscan2
- RELT | c.558C>G p.L186= | Silent (SNP) | VAF 39/371 reads (11%) | called by muse, mutect2, varscan2
- RINT1 | c.1767C>T p.S589= | Silent (SNP) | VAF 46/421 reads (11%) | called by muse, mutect2, varscan2
- RNF38 | c.699C>T p.F233= | Silent (SNP) | VAF 18/387 reads (5%) | called by muse, mutect2
- RREB1 | c.2649G>T p.S883= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV58558582; called by mutect2, varscan2
- RTN1 | c.1869C>A p.V623= | Silent (SNP) | VAF 62/632 reads (10%) | catalogued as COSV50761236; called by muse, mutect2
- RYR1 | c.9948G>T p.L3316= | Silent (SNP) | VAF 46/446 reads (10%) | called by muse, mutect2
- SACS | c.13512A>T p.A4504= | Silent (SNP) | VAF 46/668 reads (7%) | called by muse, mutect2
- SCN4A | c.1887G>T p.L629= | Silent (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- SCTR | c.840G>A p.L280= | Silent (SNP) | VAF 46/414 reads (11%) | called by muse, mutect2, varscan2
- SELENOO | c.30T>G p.A10= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- SERPING1 | c.1185C>G p.L395= | Silent (SNP) | VAF 36/653 reads (6%) | called by muse, mutect2
- SKA1 | c.723A>C p.L241= | Silent (SNP) | VAF 20/215 reads (9%) | catalogued as rs756011159; called by muse, mutect2
- SLAMF1 | c.144A>T p.T48= | Silent (SNP) | VAF 36/456 reads (8%) | called by muse, mutect2
- SLC34A3 | c.639G>A p.T213= | Silent (SNP) | VAF 58/350 reads (17%) | catalogued as rs758138530; called by muse, mutect2, varscan2
- SLC35C2 | c.714G>T p.L238= | Silent (SNP) | VAF 58/473 reads (12%) | called by muse, mutect2, varscan2
- SLITRK6 | c.1248C>A p.L416= | Silent (SNP) | VAF 23/272 reads (8%) | called by muse, mutect2
- SOX3 | c.381G>T p.A127= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- SOX9 | c.102C>T p.P34= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as rs1034958680; called by muse, mutect2
- ST8SIA4 | c.288A>T p.S96= | Silent (SNP) | VAF 51/512 reads (10%) | called by muse, mutect2, varscan2
- TBX22 | c.630C>A p.G210= | Silent (SNP) | VAF 24/268 reads (9%) | called by muse, mutect2
- TDRD5 | c.2664A>G p.A888= | Silent (SNP) | VAF 95/609 reads (16%) | called by muse, mutect2, varscan2
- TESPA1 | c.711C>A p.L237= (on ENST00000316577 / NM_001098815.3; = p.L99= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- TFAP2A | c.183C>A p.P61= (on ENST00000482890; = p.P53= on NM_001032280.3) | Silent (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- THSD7A | c.1005G>C p.G335= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as COSV70272590; called by muse, mutect2
- TJP1 | c.4239A>T p.S1413= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- TKTL2 | c.1302C>A p.A434= | Silent (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- TLR4 | c.1224C>T p.F408= (on ENST00000355622 / NM_138554.5; = p.F368= on NM_003266.4) | Silent (SNP) | VAF 42/347 reads (12%) | called by muse, mutect2, varscan2
- TLX1 | c.663C>T p.H221= | Silent (SNP) | VAF 36/270 reads (13%) | catalogued as rs149702067; called by muse, mutect2, varscan2
- TMEM161B | c.324G>C p.V108= | Silent (SNP) | VAF 67/706 reads (9%) | called by muse, varscan2
- TMEM179 | c.336G>A p.L112= | Silent (SNP) | VAF 40/266 reads (15%) | called by muse, mutect2, varscan2
- TNRC18 | c.2532G>T p.P844= | Silent (SNP) | VAF 59/225 reads (26%) | catalogued as rs375814260; called by muse, mutect2, varscan2
- TRPC4 | c.1965T>G p.T655= | Silent (SNP) | VAF 83/695 reads (12%) | catalogued as COSV58999924; called by muse, mutect2, varscan2
- TTC24 | c.1018C>T p.L340= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV63998384; called by muse, mutect2, varscan2
136 further variants in this file (0 protein-altering or splice-affecting, 15 silent, 121 other) are not listed here.
